Somatic mutation profile of tumor specimen TCGA-BQ-7061-01A (aliquot TCGA-BQ-7061-01A-11D-1961-08) from TCGA case TCGA-BQ-7061, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 83.9 years (30,662 days).
Specimen TCGA-BQ-7061-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49cda48d-5dd4-4da0-b2ad-39931499c811.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-7061-11A (Solid Tissue Normal), aliquot TCGA-BQ-7061-11A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6cd9c653-b550-48ed-afb0-b47727252bff

The open-access MAF lists 86 somatic variants for this specimen: 66 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 17, Frame Shift Del 4, Splice Site 4, Frame Shift Ins 3, Nonsense Mutation 2, 5'UTR 1, Intron 1, 5'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY2 | c.2207T>G p.F736C | Missense Mutation (SNP) | VAF 81/231 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV57903758; called by muse, mutect2, varscan2
- ARHGAP15 | c.313T>C p.S105P | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV54524950; called by muse, mutect2, varscan2
- CD86 | c.350C>G p.P117R (on ENST00000330540 / NM_175862.5; = p.P111R on NM_006889.4) | Missense Mutation (SNP) | VAF 57/67 reads (85%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV52609926, COSV52610763; called by muse, mutect2, varscan2
- CRACDL | c.2779C>G p.L927V | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV67410395; called by muse, mutect2, varscan2
- DHX9 | c.2839A>G p.M947V | Missense Mutation (SNP) | VAF 70/97 reads (72%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV62362664; called by muse, mutect2, varscan2
- DPY19L2 | c.596T>A p.I199K | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV60541843, COSV60546256; called by muse, mutect2, varscan2
- ENTPD6 | c.810G>C p.Q270H | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV61751997, COSV61752574; called by muse, mutect2, varscan2
- FAT1 | c.10385T>C p.L3462P | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71676235; called by muse, mutect2
- FOXC2 | c.69T>G p.N23K | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as COSV57445505; called by muse, mutect2, varscan2
- GBF1 | c.574C>G p.L192V | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.923); catalogued as COSV64149586; called by muse, mutect2, varscan2
- GCFC2 | c.858C>G p.H286Q | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV58083714; called by muse, mutect2, varscan2
- GOLGA4 | c.2095G>A p.A699T | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV62714259; called by muse, mutect2, varscan2
- GRK3 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs773556791, COSV60800952; called by muse, mutect2, varscan2
- GRM5 | c.3355C>T p.P1119S (on ENST00000305447 / NM_001143831.2; = p.P1087S on NM_000842.4) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.986); catalogued as rs757637314, COSV59632867; called by muse, mutect2
- GSPT2 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs782786209, COSV61215356; called by muse, mutect2, varscan2
- HERC2 | c.7376T>C p.L2459P | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.11); catalogued as rs113634395, COSV99874026; called by muse, mutect2
- IRF2 | c.408C>G p.I136M | Missense Mutation (SNP) | VAF 59/166 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV66930847; called by muse, mutect2, varscan2
- KIAA1549 | c.1409A>G p.D470G | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV54330971; called by muse, mutect2, varscan2
- KIF4A | c.3372+2T>C p.X1124_splice | Splice Site (SNP) | VAF 36/103 reads (35%) | catalogued as COSV65546257; called by muse, mutect2, varscan2
- LAS1L | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 62/187 reads (33%) | catalogued as COSV56709257; called by muse, mutect2, varscan2
- LCE2A | c.314G>C p.C105S | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV64227217; called by muse, mutect2, varscan2
- LSR | c.923-2A>G p.X308_splice (on ENST00000361790; = p.X289_splice on NM_015925.6) | Splice Site (SNP) | VAF 33/121 reads (27%) | catalogued as COSV55888487; called by muse, mutect2, varscan2
- MMP27 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52783062; called by mutect2, varscan2
- MRPL44 | c.442A>G p.M148V | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1331792075, COSV51315699; called by muse, mutect2, varscan2
- MTOR | c.1117G>T p.V373L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV63879144; called by muse, mutect2, varscan2
- MYH11 | c.2237C>A p.A746D | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV55543992, COSV55572388; called by muse, mutect2, varscan2
- NOS1 | c.4231A>G p.N1411D | Missense Mutation (SNP) | VAF 121/541 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as COSV57623190; called by muse, mutect2, varscan2
- PBRM1 | c.1542-1G>A p.X514_splice | Splice Site (SNP) | VAF 22/33 reads (67%) | catalogued as COSV56308456; called by muse, mutect2, varscan2
- POU2AF1 | c.557T>C p.L186P | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67577861; called by muse, mutect2, varscan2
- RAET1G | c.439A>G p.I147V | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.241); catalogued as rs759412849, COSV66275302; called by muse, mutect2, varscan2
- RASGRF1 | c.3676C>T p.R1226* | Nonsense Mutation (SNP) | VAF 63/192 reads (33%) | catalogued as rs1457729097, COSV67251376; called by muse, mutect2, varscan2
- SAMD9 | c.872A>C p.E291A | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV66077925; called by muse, mutect2, varscan2
- SIN3B | c.953T>C p.L318P | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56136931; called by muse, mutect2, varscan2
- SLC6A13 | c.611T>A p.L204Q | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV58260960; called by muse, mutect2, varscan2
- SLC7A4 | c.1079T>A p.V360E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100298715; called by mutect2, varscan2
- SLITRK2 | c.690G>C p.W230C | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59429427; called by muse, varscan2
- SLITRK2 | c.692T>A p.L231Q | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59429448; called by muse, varscan2
- SMAD1 | c.1146T>G p.I382M | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV57473662; called by muse, mutect2, varscan2
- SNRPC | c.149T>C p.I50T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as COSV55075224, COSV55076540; called by muse, mutect2, varscan2
- SPEG | c.665C>G p.P222R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as COSV56680948; called by muse, mutect2, varscan2
- ST6GALNAC2 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 16/41 reads (39%) | PolyPhen benign (0.063); catalogued as rs776553153, COSV56571534; called by muse, mutect2, varscan2
- TAS2R13 | c.32T>G p.L11R | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV66831919; called by muse, mutect2, varscan2
- TCTE1 | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV65256016; called by muse, mutect2, varscan2
- TDRD6 | c.4682G>C p.R1561T | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV60179284; called by muse, mutect2, varscan2
- TENT5A | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.202); catalogued as COSV60789765; called by muse, mutect2, varscan2
- TEP1 | c.1484C>T p.P495L | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV53001426; called by muse, mutect2, varscan2
- TLN2 | c.2899C>G p.Q967E | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.065); catalogued as COSV60889822, COSV60896716; called by muse, mutect2, varscan2
- TP53BP1 | c.1651A>T p.M551L | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55510976; called by muse, mutect2, varscan2
- TRMT1 | c.399A>T p.E133D | Missense Mutation (SNP) | VAF 96/267 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV52836220; called by muse, mutect2, varscan2
- TSR1 | c.1787T>A p.M596K | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV56787492; called by muse, mutect2, varscan2
- UGT3A2 | c.960T>G p.F320L | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as COSV56933906; called by muse, mutect2, varscan2
- USP34 | c.7735C>G p.R2579G | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as COSV68407628; called by muse, varscan2
- XIRP2 | c.5115T>A p.H1705Q (on ENST00000628543; = p.H1880Q on NM_152381.6) | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV54738377; called by muse, mutect2, varscan2
- ZFHX4 | c.973A>T p.I325F | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV51499815; called by muse, mutect2, varscan2
- ZMYM6 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs753597685, COSV64120086, COSV64122185; called by muse, mutect2, varscan2
- ZP2 | c.893A>T p.Q298L | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV54817314; called by muse, mutect2, varscan2
- ZSCAN4 | c.368C>G p.T123S | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as COSV59001999; called by muse, mutect2, varscan2
- ANKRD26 | c.1505_1507dup p.M502dup | In Frame Ins (INS) | VAF 39/125 reads (31%) | called by mutect2, pindel, varscan2
- ASPM | c.4407dup p.I1470Yfs*7 | Frame Shift Ins (INS) | VAF 36/60 reads (60%) | called by mutect2, pindel, varscan2
- MGA | c.6016_6034del p.N2006Qfs*10 (on ENST00000219905 / NM_001164273.1; = p.N1797Qfs*10 on NM_001080541.2) | Frame Shift Del (DEL) | VAF 28/108 reads (26%) | called by mutect2, pindel, varscan2
- NCAPD3 | c.3229del p.Q1077Sfs*11 | Frame Shift Del (DEL) | VAF 30/87 reads (34%) | called by mutect2, pindel, varscan2
- ORC5 | c.733_733+12del p.X245_splice | Splice Site (DEL) | VAF 7/22 reads (32%) | called by mutect2, pindel, varscan2
- PDE7B | c.1164dup p.W389Mfs*7 | Frame Shift Ins (INS) | VAF 8/30 reads (27%) | called by pindel, varscan2
- SETD2 | c.2012del p.L671* | Frame Shift Del (DEL) | VAF 59/93 reads (63%) | called by mutect2, pindel, varscan2
- VPS35L | c.2891dup p.*964Wfs*55 | Frame Shift Ins (INS) | VAF 20/75 reads (27%) | called by mutect2, pindel, varscan2
- ZNF564 | c.17_18del p.S6* | Frame Shift Del (DEL) | VAF 38/132 reads (29%) | called by pindel, varscan2
- ABCC2 | c.1869C>T p.D623= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV64988856; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1755G>C p.L585= | Silent (SNP) | VAF 87/113 reads (77%) | catalogued as rs1250663566, COSV53686533; called by muse, mutect2, varscan2
- ATN1 | c.1935C>G p.S645= | Silent (SNP) | VAF 47/84 reads (56%) | catalogued as COSV63113294; called by muse, mutect2, varscan2
- GLMN | c.1776G>C p.G592= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV64860751; called by muse, mutect2
- GNAI1 | c.831A>G p.K277= | Silent (SNP) | VAF 70/239 reads (29%) | catalogued as COSV63525525; called by muse, mutect2, varscan2
- GSPT2 | c.237G>T p.P79= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV61213736, COSV61215347; called by muse, mutect2, varscan2
- IGHV3-72 | c.354T>G p.A118= | Silent (SNP) | VAF 73/187 reads (39%) | catalogued as COSV70409804; called by muse, mutect2, varscan2
- MYO1E | c.1395C>T p.D465= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs759846809, COSV55696435; called by muse, mutect2, varscan2
- PITPNM3 | c.1416G>A p.Q472= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV52600673; called by muse, mutect2
- PPARD | c.654A>C p.T218= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV61101731; called by muse, mutect2, varscan2
- RFX4 | c.1956T>A p.T652= (on ENST00000392842 / NM_213594.3; = p.T558= on NM_032491.6) | Silent (SNP) | VAF 257/480 reads (54%) | catalogued as COSV57575467, COSV57582204; called by muse, mutect2, varscan2
- RIMBP2 | c.2142C>T p.D714= | Silent (SNP) | VAF 29/192 reads (15%) | catalogued as COSV55485746; called by muse, mutect2, varscan2
- ROS1 | c.2292A>T p.G764= | Silent (SNP) | VAF 49/110 reads (45%) | catalogued as COSV63862428; called by muse, mutect2, varscan2
- SLC26A5 | c.1458T>C p.Y486= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as rs1333402811, COSV59706590; called by muse, mutect2, varscan2
- SLITRK2 | c.691C>T p.L231= | Silent (SNP) | VAF 47/165 reads (28%) | catalogued as COSV59429441; called by muse, varscan2
- USF3 | c.2970A>G p.S990= | Silent (SNP) | VAF 92/119 reads (77%) | catalogued as COSV57074265; called by muse, mutect2, varscan2
- ZFHX4 | c.972G>T p.G324= | Silent (SNP) | VAF 53/136 reads (39%) | catalogued as COSV51499167; called by muse, mutect2, varscan2
- FAM72A | c.-1del | 5'UTR (DEL) | VAF 61/188 reads (32%) | called by mutect2, pindel, varscan2
- GATA3 | chr10:8050928 G>A | 5'Flank (SNP) | VAF 7/19 reads (37%) | catalogued as rs372474960; called by muse, varscan2
- KHK | c.210-321T>A | Intron (SNP) | VAF 34/111 reads (31%) | catalogued as COSV53157748; called by muse, mutect2, varscan2
